Surgical pathology report (de-identified scan), TCGA case TCGA-BB-4228, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-4228-01A (Primary Tumor).

URG PATH REPORT
LECTION DATE/TIME

1st Specimen collected
Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

1. ANTERIOR TONGUE MUCOSA (EXCISION): NEGATIVE FOR TUMOR.
2. DEEP ANTERIOR (EXCISION): NEGATIVE FOR TUMOR.
3. DEEP LATERAL PHARYNGEAL (EXCISION): NEGATIVE FOR TUMOR.
4. BASE OF TONGUE MUCOSA (EXCISION): NEGATIVE FOR TUMOR.
5. DEEP TONSIL (EXCISION): NEGATIVE FOR TUMOR.
6. DEEP BIOPSY VALLECULA (EXCISION): NEGATIVE FOR TUMOR.
7. RIGHT BASE OF TONGUE (RESECTION): INFILTRATING HPV-RELATED SQUAMOUS CELL CARCINOMA (6 CM). THE CARCINOMA INVADES TO A MAXIMUM DEPTH OF 1.3 CM. THE CARCINOMA EXTENDS TO THE DEEP AND LATERAL MARGINS, AND IT CLOSELY APPROACHES (< 0.1 CM) THE MEDIAL MARGIN.

See [REDACTED] for official report.

Reported by:

Final Report Signed on

TCGA-BB-4228

*** Unofficial lab results - do not file in patient chart. ***
*** Contact medical records for official chart copy. ***
UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file 1ce30124-b075-475b-8472-4bea0b44b334 (TCGA-BB-4228.39956346-2D64-4D6A-8B64-A0E8C2406515.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).